Somatic mutation profile of tumor specimen 0DUCTY from CCDI case PBCLBR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male.
Specimen 0DUCTY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5eb837c7-4d62-4db2-9ecf-123b9c98ad81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUCRL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32352d00-3ecf-4b0c-a5b3-4efa8df01eae

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 415/1022 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- NCAN | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 19/455 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1393603592, COSV53056780; called by muse, mutect2
- TRIM29 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 58/436 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV100531582; called by muse, mutect2, varscan2
- NOX3 | c.1099T>C p.F367L | Missense Mutation (SNP) | VAF 39/853 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.197); called by muse, mutect2
- SERPINE1 | c.773T>G p.M258R | Missense Mutation (SNP) | VAF 46/570 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COLEC12 | c.1548G>A p.K516= | Silent (SNP) | VAF 32/433 reads (7%) | called by muse, mutect2
- LAMA3 | c.5736T>C p.N1912= (on ENST00000313654 / NM_198129.4; = p.N303= on NM_000227.6) | Silent (SNP) | VAF 70/1132 reads (6%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 9/254 reads (4%) | called by muse, mutect2
- CCDC149 | c.63+17714C>A | Intron (SNP) | VAF 18/538 reads (3%) | catalogued as rs1341369251; called by muse, mutect2
- CCDC149 | c.63+17713T>G | Intron (SNP) | VAF 18/523 reads (3%) | called by muse, mutect2
- PGAM5 | c.192-15G>A | Intron (SNP) | VAF 28/559 reads (5%) | called by muse, mutect2
